Somatic mutation profile of tumor specimen MMRF_2568_1_BM_CD138pos (aliquot MMRF_2568_1_BM_CD138pos_T1_KHS5U_L12867) from MMRF case MMRF_2568, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.9 years (25,526 days).
Specimen MMRF_2568_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 267ce325-95f4-4e36-8d2e-d52c9b884ec6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2568_2_PB_Whole (Blood Derived Normal), aliquot MMRF_2568_2_PB_Whole_C1_KHS5U_L12868; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0794827f-5809-4fbf-a106-c5ad069c3366

The open-access MAF lists 92 somatic variants for this specimen: 40 protein-altering or splice-affecting, 11 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 19, Intron 12, Silent 11, 5'UTR 5, RNA 2, Nonsense Mutation 2, Splice Region 2, 5'Flank 2, Splice Site 2, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 46/57 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSBG1 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs772359349, COSV51906138; called by muse, mutect2, varscan2
- CFAP221 | c.1957G>C p.D653H | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV54661801; called by muse, mutect2, varscan2
- CST5 | c.175A>T p.I59F | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV100489620; called by muse, mutect2, varscan2
- EXOC4 | c.415C>G p.Q139E | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV54085750; called by muse, mutect2, varscan2
- IGHV3-33 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as rs371479041; called by muse, mutect2, varscan2
- LCMT2 | c.1507G>A p.V503M | Missense Mutation (SNP) | VAF 89/244 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.799); catalogued as rs1362073591, COSV59789623; called by muse, mutect2, varscan2
- PKDCC | c.1035-6C>T | Splice Region (SNP) | VAF 116/242 reads (48%) | catalogued as rs746449609; called by muse, mutect2, varscan2
- SLC47A2 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1360933081; called by muse, mutect2, varscan2
- USP30 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1433924278; called by muse, mutect2, varscan2
- ABCA6 | c.703G>C p.V235L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ADNP | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ADORA2A | c.967G>C p.V323L | Missense Mutation (SNP) | VAF 105/297 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMOT | c.2503G>A p.E835K (on ENST00000371959 / NM_001113490.1; = p.E426K on NM_133265.3) | Missense Mutation (SNP) | VAF 49/49 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- BRINP2 | c.1867C>T p.Q623* | Nonsense Mutation (SNP) | VAF 61/123 reads (50%) | called by muse, mutect2, varscan2
- CCDC183 | c.271-8C>T | Splice Region (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
- CCNB3 | c.3299C>T p.S1100L | Missense Mutation (SNP) | VAF 113/120 reads (94%) | SIFT tolerated (0.08); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- CDK19 | c.8A>T p.Y3F | Missense Mutation (SNP) | VAF 145/292 reads (50%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- COL1A1 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- DENND4C | c.4577C>T p.S1526F (on ENST00000434457 / NM_001330640.2; = p.S1477F on NM_017925.7) | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FOXO1 | c.208T>C p.F70L | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- HAUS5 | c.697-2A>G p.X233_splice | Splice Site (SNP) | VAF 35/64 reads (55%) | called by muse, mutect2, varscan2
- HUWE1 | c.9118G>A p.E3040K | Missense Mutation (SNP) | VAF 102/105 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- IGHV2-70D | c.158T>A p.M53K | Missense Mutation (SNP) | VAF 70/80 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, varscan2
- IGKV1D-43 | c.46T>G p.W16G | Missense Mutation (SNP) | VAF 37/41 reads (90%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- LGI1 | c.433A>C p.S145R | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, varscan2
- LRMDA | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); called by muse, mutect2
- MMS22L | c.1744G>C p.A582P | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- PKHD1 | c.4451C>A p.A1484E | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- POLR2M | c.900del p.T301Rfs*6 | Frame Shift Del (DEL) | VAF 54/134 reads (40%) | called by mutect2, pindel, varscan2
- PPFIA2 | c.3725C>T p.S1242L | Missense Mutation (SNP) | VAF 136/362 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SLC9A7 | c.1029+2T>C p.X343_splice | Splice Site (SNP) | VAF 32/33 reads (97%) | called by mutect2, varscan2
- SPTA1 | c.2062C>A p.Q688K | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ST6GALNAC5 | c.602C>A p.A201D | Missense Mutation (SNP) | VAF 83/176 reads (47%) | PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- SULT2A1 | c.118T>A p.L40M | Missense Mutation (SNP) | VAF 84/189 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- SYT14 | c.1238A>G p.H413R | Missense Mutation (SNP) | VAF 96/252 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- TTC3 | c.2348T>A p.L783* | Nonsense Mutation (SNP) | VAF 51/83 reads (61%) | called by muse, mutect2, varscan2
- UNC13A | c.1190A>G p.D397G | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- UTS2R | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADORA2B | c.600G>A p.V200= | Silent (SNP) | VAF 67/169 reads (40%) | called by muse, mutect2, varscan2
- CTCF | c.414T>C p.Y138= | Silent (SNP) | VAF 92/228 reads (40%) | catalogued as rs1288680975; called by muse, mutect2, varscan2
- FGA | c.489G>A p.L163= | Silent (SNP) | VAF 115/258 reads (45%) | catalogued as rs749273086; called by muse, mutect2, varscan2
- IGHV2-70 | c.168C>T p.S56= | Silent (SNP) | VAF 101/164 reads (62%) | catalogued as rs367953381; called by muse, varscan2
- LRP1B | c.6858A>G p.T2286= | Silent (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2, varscan2
- LRRC53 | c.63C>T p.L21= | Silent (SNP) | VAF 133/294 reads (45%) | called by muse, mutect2, varscan2
- MUC16 | c.2553T>G p.S851= | Silent (SNP) | VAF 61/103 reads (59%) | called by muse, mutect2, varscan2
- NRXN3 | c.1506C>T p.P502= | Silent (SNP) | VAF 108/323 reads (33%) | catalogued as rs756253657; called by muse, mutect2, varscan2
- OTUD6A | c.822G>A p.P274= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- PCLO | c.2289C>A p.T763= | Silent (SNP) | VAF 55/115 reads (48%) | called by muse, mutect2, varscan2
- UNC5D | c.1191C>T p.V397= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs1178293816; called by muse, mutect2, varscan2
- ABI3BP | c.1577-8365C>T | Intron (SNP) | VAF 89/214 reads (42%) | catalogued as rs948796273; called by muse, mutect2, varscan2
- ACTR1A | c.750+82G>A | Intron (SNP) | VAF 12/13 reads (92%) | called by muse, mutect2, varscan2
- ADA | c.*161C>T | 3'UTR (SNP) | VAF 76/144 reads (53%) | catalogued as rs922396944; called by muse, mutect2, varscan2
- BICD2 | c.2470-184C>G | Intron (SNP) | VAF 32/89 reads (36%) | called by muse, mutect2, varscan2
- C15orf54 | n.711G>A | RNA (SNP) | VAF 107/288 reads (37%) | catalogued as rs754155868; called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81947600 G>C | 3'Flank (SNP) | VAF 35/100 reads (35%) | called by muse, mutect2, varscan2
- CCDC40 | c.2619+47G>A | Intron (SNP) | VAF 12/24 reads (50%) | catalogued as rs769619144; called by muse, mutect2, varscan2
- CD81 | c.-209G>T | 5'UTR (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- CNTROB | c.2586+35A>G | Intron (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
- CPNE1 | c.*84C>T | 3'UTR (SNP) | VAF 105/247 reads (43%) | called by muse, mutect2, varscan2
- CYP46A1 | c.*333G>T | 3'UTR (SNP) | VAF 189/453 reads (42%) | called by muse, mutect2, varscan2
- DHFR | c.*884C>T | 3'UTR (SNP) | VAF 20/70 reads (29%) | catalogued as rs1254828225; called by muse, varscan2
- FAF1 | c.*1628G>A | 3'UTR (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- FMO6P | n.1376G>T | RNA (SNP) | VAF 92/215 reads (43%) | called by muse, mutect2, varscan2
- GPX8 | c.*1181C>T | 3'UTR (SNP) | VAF 51/110 reads (46%) | called by muse, mutect2, varscan2
- HPS5 | c.2718-137T>A | Intron (SNP) | VAF 37/96 reads (39%) | called by muse, mutect2, varscan2
- IGLL5 | c.*150_*151del | 3'UTR (DEL) | VAF 252/388 reads (65%) | called by mutect2, pindel, varscan2
- KBTBD6 | c.*1014C>T | 3'UTR (SNP) | VAF 33/99 reads (33%) | called by muse, mutect2, varscan2
- KCNIP3 | c.*961C>G | 3'UTR (SNP) | VAF 39/124 reads (31%) | catalogued as COSV54668034; called by muse, mutect2, varscan2
- KIAA1210 | c.*2031C>T | 3'UTR (SNP) | VAF 76/86 reads (88%) | called by muse, mutect2, varscan2
- LIMD2 | c.85-24_85-22delinsAA | Intron (DEL) | VAF 43/161 reads (27%) | called by pindel, varscan2*
- MIER3 | c.*2175G>A | 3'UTR (SNP) | VAF 43/80 reads (54%) | called by muse, mutect2, varscan2
- NRXN1 | c.3365-110438A>C | Intron (SNP) | VAF 87/183 reads (48%) | called by muse, mutect2, varscan2
- PCBP1 | c.-225C>T | 5'UTR (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- PCNX2 | c.4076+16C>T | Intron (SNP) | VAF 42/182 reads (23%) | called by muse, mutect2, varscan2
- POGLUT2 | c.-107G>A | 5'UTR (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- RAD21 | chr8:116876151 C>A | 5'Flank (SNP) | VAF 38/78 reads (49%) | called by muse, mutect2, varscan2
- RAP2A | c.-278C>T | 5'UTR (SNP) | VAF 11/22 reads (50%) | catalogued as rs1282688721; called by muse, mutect2, varscan2
- RMI1 | c.*1062A>G | 3'UTR (SNP) | VAF 50/101 reads (50%) | catalogued as COSV57935323; called by muse, mutect2, varscan2
- SETD4 | c.*1209C>T | 3'UTR (SNP) | VAF 39/132 reads (30%) | called by muse, mutect2, varscan2
- SLC47A1 | c.*1217G>T | 3'UTR (SNP) | VAF 43/137 reads (31%) | called by muse, mutect2, varscan2
- SLC47A1 | c.*1358G>T | 3'UTR (SNP) | VAF 60/149 reads (40%) | called by muse, mutect2, varscan2
- SOX11 | c.*6169G>T | 3'UTR (SNP) | VAF 43/124 reads (35%) | called by muse, mutect2, varscan2
- SPOCK1 | c.*2713T>C | 3'UTR (SNP) | VAF 42/91 reads (46%) | catalogued as rs1439590953; called by muse, mutect2, varscan2
- SPON1 | c.-8C>T | 5'UTR (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2
- SPRY2 | c.*21A>G | 3'UTR (SNP) | VAF 97/228 reads (43%) | called by muse, mutect2, varscan2
- STK32A | c.*1699G>A | 3'UTR (SNP) | VAF 42/107 reads (39%) | catalogued as rs972601538; called by muse, mutect2, varscan2
- TEX51 | c.382+32G>T | Intron (SNP) | VAF 49/111 reads (44%) | called by muse, mutect2, varscan2
- TFDP2 | c.187-41A>C | Intron (SNP) | VAF 41/90 reads (46%) | called by muse, mutect2, varscan2
- TFEB | chr6:41736160 T>C | 5'Flank (SNP) | VAF 154/405 reads (38%) | called by muse, varscan2
- ZNF169 | c.160+121C>T | Intron (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
